Gene-level copy-number profile of tumor specimen TCGA-DX-A6YV-01A from TCGA case TCGA-DX-A6YV, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 74.1 years (27,053 days).
Specimen TCGA-DX-A6YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.26e12bdc-5d33-40f6-ae06-34c4e8adc5d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6YV-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef66b010-632d-45b6-85a7-ca7d26519d34

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,788; copy number 2: 28,382; copy number 3: 14,263; copy number 4: 11,899; copy number 5: 2,921; copy number 6: 194; copy number 7: 301; copy number 8: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6YV-01A-12D-A350-01): tumor purity 0.94, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,941,217–128,067,901, 3 genes (within-gene range 0–5): SAP130, AC108059.2, Y_RNA.
- chr17:7,591,230–7,833,744, 9 genes (within-gene range 0–3): FXR2, SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3, DNAH2, RPL29P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,472 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,064,711–152,720,470, 279 genes, copy number 5 (broad region; genes not listed).
- chr1:158,418,210–161,964,070, 171 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:162,561,506–162,979,793, 8 genes, copy number 5 (within-gene range 2–5): UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1.
- chr1:228,687,415–229,383,188, 14 genes, copy number 5: FTH1P2, RHOU, AL078624.2, AL078624.1, LINC02815, ISCA1P2, LINC02814, AL162595.2, TMEM78, AL162595.1, RAB4A, AL117350.1, CCSAP, RNU6-180P.
- chr2:94,791,103–96,642,787, 80 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:118,766,965–120,351,803, 31 genes, copy number 5 (within-gene range 0–5): LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB.
- chr2:123,065,321–127,931,440, 65 genes, copy number 5 (broad region; genes not listed).
- chr3:11,745–7,790,482, 70 genes, copy number 5 (broad region; genes not listed).
- chr11:27,888,838–41,857,733, 172 genes, copy number 5 (broad region; genes not listed).
- chr16:76,634,998–79,212,667, 39 genes, copy number 5 (within-gene range 3–5): LINC02125, AC106729.1, MIR4719, AC106734.1, AC106733.1, MON1B, SYCE1L, AC009139.2, VN2R10P, AC009139.1, ADAMTS18, AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2, WWOX, AC079414.3, AC009044.1, WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1.
- chr17:142,789–5,175,034, 229 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:5,360,963–5,419,676, 1 gene, copy number 8 (within-gene range 3–8): NUP88.
- chr17:5,419,641–7,030,290, 55 genes, copy number 8: RPAIN, AC004148.1, C1QBP, DHX33, DHX33-DT, DERL2, MIS12, AC055839.2, NLRP1, AC055839.1, AC135726.1, AC006236.1, AC007846.1, AC007846.2, WSCD1, AC104770.1, RNU6-1264P, BTF3P14, AC055872.2, AIPL1, AC055872.1, PIMREG, PITPNM3, Metazoa_SRP, KIAA0753, RNA5SP435, AC004706.3, TXNDC17, MED31, C17orf100, AC004706.1, MIR4520-1, MIR4520-2, ALOX15P1, SLC13A5, AC004706.2, RPL23AP73, XAF1, PRAL, FBXO39, TEKT1, ALOX12P2, ALOX12-AS1, AC027763.1, AC027763.2, AC040977.2, AC040977.1, ALOX12, RNASEK, RNASEK-C17orf49, C17orf49, MIR497HG, MIR195, MIR497, BCL6B.
- chr17:8,474,207–28,617,377, 593 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr17:29,071,122–29,180,398, 1 gene, copy number 7 (within-gene range 2–7): MYO18A.
- chr17:29,140,483–29,254,494, 4 genes, copy number 7: AC024619.3, AC005412.1, TWF1P1, CRYBA1.
- chr17:49,230,853–49,678,163, 19 genes, copy number 5 (within-gene range 3–5): FLJ40194, MIR6129, ZNF652, AC091180.2, AC091180.5, AC091180.4, AC091180.1, PHB, AC091180.3, Y_RNA, EIF4EP2, LINC02075, AC015656.1, NGFR, AC006487.1, MIR6165, AC006487.2, NXPH3, SPOP.
- chr17:54,754,165–76,711,016, 625 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:5,558,167–6,199,572, 29 genes, copy number 5 (within-gene range 3–5): TINCR, SNRPEP4, SAFB2, SAFB, RPL36, MICOS13, HSD11B1L, LONP1, CATSPERD, PRR22, AC011499.1, DUS3L, NRTN, FUT6, FUT3, AC024592.2, FUT5, AC024592.3, NDUFA11, AC024592.1, AC104532.1, VMAC, AC104532.2, CAPS, RANBP3, AC011444.1, RFX2, AC011444.2, AC011444.4.
- chr19:6,562,123–28,125,430, 952 genes, copy number 5 (broad region; genes not listed).
- chr19:29,287,011–29,921,653, 14 genes, copy number 6 (within-gene range 2–6): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58.
- chr19:32,345,594–32,978,229, 21 genes, copy number 6 (within-gene range 4–6): ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24.

Autosomal genes at a single copy (total copy number 1): 566. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
